TCGA case TCGA-BR-4191 — Stomach Adenocarcinoma (TCGA-STAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach; Tissue source site: Asterand. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/74f859cf-6df5-4e96-ae6b-cfaab691d5fd

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Russia; Age at index: 72 years; Vital status: Dead; Days to death: 558 days (1.5 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C16.9; Tissue or organ of origin: Stomach, NOS; Site of resection or biopsy: Stomach, NOS; Classification of tumor: primary; Age at diagnosis: 72.7 years (26,562 days); Year of diagnosis: 2008; AJCC staging edition: 6th; AJCC pathologic T: TX; AJCC pathologic N: N1; AJCC pathologic M: M0; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: RX.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 3; Lymph nodes tested: 8.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Days to treatment start: 3 days; Days to treatment end: 104 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Docetaxel; Treatment intent type: Adjuvant; Days to treatment start: 3 days; Days to treatment end: 104 days; Number of cycles: 4; Treatment dose: 300 mg/m2; Prescribed dose: 75; Prescribed dose units: mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil; Days to treatment start: 3 days; Days to treatment end: 104 days.
   Recorded as not given: adjuvant Radiation Therapy, NOS.

Follow-up (1 entry)
- Follow-up contacts recording only the day: day 0, day 558.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-BR-4191-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 2.4; Intermediate dimension: 2; Shortest dimension: 0.5.
  Slide TCGA-BR-4191-01A-01-BS1: Section location: Top; Percent tumor cells: 91; Percent tumor nuclei: 85; Percent normal cells: 2; Percent necrosis: 2; Percent stromal cells: 5.
  Slide TCGA-BR-4191-01A-02-BS2: Section location: Bottom; Percent tumor cells: 88; Percent tumor nuclei: 85; Percent normal cells: 5; Percent necrosis: 2; Percent stromal cells: 5.
- Sample TCGA-BR-4191-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-BR-4191-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 2.5; Intermediate dimension: 1.6; Shortest dimension: 0.4.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Stomach, Adenocarcinoma, Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Lymph nodes examined: Yes; Cancer procurement city: Kazan; Antireflux treatment: No.
- Drug treatment 1: Regimen number: 1.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 3: Pharmaceutical therapy drug name: 5-Fluorouracil.
- Follow-up form: New tumor event diagnosis indicator: No; Cause of death: Stomach Cancer.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 558 days; disease-specific survival: event status not recorded, 558 days; progression-free interval: no event (censored), 558 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-BR-4191-01A-02D-1130-01): tumor purity 0.51, ploidy 2.1, whole-genome doublings 0.
